Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1HB, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1HB-01A (Primary Tumor).

ICD-0-3

Adenocarcinoma, mucinous, NOS 8480/3

Site: Transverse colon C18.4

2/10/11

(First Tumor)

Tumor Site:	Transverse Colon		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Moderately Differentiated		
Mucinous:	☐ No	☐ Yes	☒ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☐ No	☒ Yes	☐ Unknown
Host Response:	Lymphoid Aggregates		
Crohn's like reaction	☐ None	☒ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☐ Expansile	☐ Invasive	☒ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown
Mutator Phenotype:	☐ No	☒ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☐ No	☐ Yes	☒ Yes (Focal) ☐ Unknown
TIL Cells / HPF	2.4		
Pathologist Comment:			

Source: NCI Genomic Data Commons file 64a201dd-6982-463c-aa81-b208f3a418d4 (TCGA-DM-A1HB.B16DE561-4A84-4E00-AFF8-CA8A5203D6D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).